Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A91Q, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A91Q-01A (Primary Tumor).

[page 1 of 2]
Collect date:

ICD O-3
Adenocarcinoma, tubular 8211/3
Site: Cardia NOS C16.2
JW 3/18/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Cardia)

I-)Product of esophagogastrrectomy:

- Poorly differentiated tubular adenocarcinoma of cardia, with largest tumor size measuring 6.5 cm.
- Tumor infiltrates distal esophagus including adventitia.
- Tumor infiltrates stomach wall including perigastric fat.
- Presence of foci of lymphatic invasion and perineural invasion.
- Margin in esophageal adventitia involved by neoplasia.
- Proximal and distal margins uninvolved by neoplasia.

Lymphadenectomy according to standardization:

Right paracardic lymph nodes:

- Metastatic adenocarcinoma (2/2), with capsular invasion.

Left paracardic lymph nodes:

- Metastatic adenocarcinoma (2/2), with capsular invasion.

Lesser curvature lymph nodes:

- Metastatic adenocarcinoma (8/8), with capsular invasion.

Suprapyloric lymph node:

- Uninvolved by neoplasia (0/1).
- Lymphatic neoplastic thrombi in perilymph node fat.

Left gastric artery lymph nodes:

- Metastatic adenocarcinoma (8/8), with capsular invasion.
- Lymphatic neoplastic thrombi in perilymph node fat.

Celiac trunk lymph nodes:

- Metastatic adenocarcinoma (4/6), with capsular invasion.
- Lymphatic neoplastic thrombi in perilymph node fat.

Paraesophageal lymph node:

- Metastatic adenocarcinoma (1/1), without capsular invasion.
- Lymphatic neoplastic thrombi in perilymph node fat.

II-)Esophageal margin:

Uninvolved by neoplasia.

[page 2 of 2]
III-)Omentum:
Uninvolved by neoplasia.

IV-)Gallbladder:
-Cholelithiasis.

Histologic Discrepancy		✓
Case is (Un)able to be QUALIFIED		✓

Source: NCI Genomic Data Commons file 48650d10-dcaa-4638-9872-c1bff4aa11da (TCGA-VQ-A91Q.6EEBDC60-AE5B-4A17-A717-008CE8FA6E4D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).